Gene-level copy-number profile of tumor specimen TCGA-66-2785-01A from TCGA case TCGA-66-2785, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.1 years (23,772 days).
Specimen TCGA-66-2785-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.4cac94cc-5d30-4835-8c7d-880bfb952c89.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2785-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/093d71e1-3682-4f7e-8cc4-3f5d5155dc4b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 838; copy number 2: 22,606; copy number 3: 18,459; copy number 4: 10,748; copy number 5: 6,430; copy number 6: 16; copy number 7: 34; copy number 8: 452; copy number 10: 88; copy number 12: 143.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2785-01A-01D-0844-01): tumor purity 0.4, ploidy 3.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,163 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,047,314–76,634,603, 817 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).
- chr3:11,745–9,855,138, 108 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr5:41,585,882–42,191,523, 11 genes, copy number 6: AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1.
- chr6:34,279,679–114,471,705, 1,162 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:113,950,886–145,066,685, 511 genes, copy number 5 (broad region; genes not listed).
- chr10:42,149,310–42,997,681, 30 genes, copy number 5: KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8, BX322639.1, CCNYL2, AL391099.1, LINC00839, ZNF37BP, FXYD6P1, EIF3LP2, ZNF33B, AL022345.3, AL022345.1, AL022345.2, RNU6-1170P, AL022345.4, LINC01518, VN1R54P, CUBNP1, LINC02632, RSU1P1, DUXAP3, AL022344.1, BMS1, RNU6-885P, LINC02623, LINC01264, MIR5100.
- chr10:49,734,641–50,133,509, 14 genes, copy number 5: OGDHL, MAPK6P6, RPL21P89, PARG, RPL35AP24, TIMM23B, TIMM23B-AGAP6, SNORA74C-2, RNA5SP317, AL442003.1, AGAP6, FAM21EP, SLC9A3P3, WASHC2A.
- chr10:50,305,586–50,625,163, 1 gene, copy number 5 (within-gene range 2–5): SGMS1.
- chr10:50,472,814–52,298,423, 22 genes, copy number 5–6 (within-gene range 2–6): AL117341.1, RNU7-107P, SGMS1-AS1, SHQ1P1, BEND3P1, NUTM2HP, AL589794.1, CTSLP4, PGGT1BP1, AL589794.2, ASAH2B, A1CF, AL512366.1, CCDC58P2, AL731537.2, PRKG1, AL731537.1, AC022537.1, MIR605, AC069079.1, RSU1P3, CSTF2T.
- chr12:66,767–12,211,084, 445 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr12:12,155,262–12,155,772, 1 gene, copy number 7: AC007537.1.
- chr15:53,910,769–53,914,712, 1 gene, copy number 7: AC084759.3.
- chr16:35,134,514–35,529,318, 39 genes, copy number 5: VN1R69P, AC023824.5, AC023824.6, UBE2MP1, SLC25A1P4, AC023824.1, AC023824.2, AC023824.4, AC023824.3, TP53TG3GP, RARRES2P5, FGFR3P5, FRG2JP, RARRES2P6, AGGF1P8, FRG2HP, RARRES2P9, AGGF1P9, C2orf69P4, LINC01566, FRG2GP, AGGF1P4, FRG2IP, RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, AC018558.6, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP, AC018558.5.
- chr19:8,389,981–11,197,791, 143 genes, copy number 12 (within-gene range 2–12) (broad region; genes not listed).
- chr19:27,638,483–47,273,701, 840 genes, copy number 5 (broad region; genes not listed).
- chr20:47,160,838–64,313,132, 414 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 831. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
